Somatic mutation profile of tumor specimen TCGA-FG-A4MT-01A (aliquot TCGA-FG-A4MT-01A-11D-A26M-08) from TCGA case TCGA-FG-A4MT, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G2; Age at diagnosis: 27.6 years (10,082 days).
Specimen TCGA-FG-A4MT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6752b9b1-163b-48f7-b0ce-09db5452329a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A4MT-10A (Blood Derived Normal), aliquot TCGA-FG-A4MT-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dca5dfc7-29cc-40a7-9382-1db1e4dbf512

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 26/65 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 31/65 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic; called by muse, varscan2
- DSP | c.4108A>T p.I1370F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV65792467; called by muse, mutect2, varscan2
- DUSP5 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV63645750; called by muse, mutect2, varscan2
- GRK2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs868080683, COSV57951642; called by muse, mutect2
- INPP4B | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as rs200327044, COSV53722669; called by muse, mutect2, varscan2
- KMT2D | c.15803T>C p.I5268T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1051071277, COSV56434754; called by muse, mutect2, varscan2
- LAMA3 | c.3881G>A p.R1294Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs547742221, COSV58067667; called by muse, mutect2, varscan2
- LDLRAP1 | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV65473474; called by muse, mutect2
- MPPED1 | c.464A>G p.D155G | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68837978; called by muse, mutect2, varscan2
- MUC16 | c.7123A>G p.N2375D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67462425; called by muse, mutect2, varscan2
- OR6F1 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as rs375716782, COSV100129389; called by muse, mutect2, varscan2
- SPANXD | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781909487, COSV100982271, COSV65152551; called by muse, mutect2
- TRRAP | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs782009444, COSV62843436; called by muse, mutect2, varscan2
- TTN | c.42962C>T p.T14321I (on ENST00000591111; = p.T6897I on NM_003319.4) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | PolyPhen probably damaging (0.976); catalogued as COSV60018509; called by muse, mutect2, varscan2
- ATRX | c.5819_5822del p.D1940Vfs*14 | Frame Shift Del (DEL) | VAF 119/331 reads (36%) | called by mutect2, pindel, varscan2
- PPRC1 | c.1308G>A p.P436= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs749670501, COSV53384975; called by muse, mutect2, varscan2
- UBD | c.219C>A p.T73= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV63542279; called by muse, mutect2
- ZNF503 | c.1374G>A p.A458= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV65307344; called by muse, mutect2, varscan2
